Somatic mutation profile of tumor specimen 0DR0CU from CCDI case PBCFRK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 12.8 years (4,657 days).
Specimen 0DR0CU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f46ddaf-6b00-41f7-9ca7-887054c4af6d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR0CD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09eef610-3026-4e8d-97e7-9db92ce5d329

The open-access MAF lists 26 somatic variants for this specimen: 22 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Intron 2, Silent 2, Splice Region 2, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 293/1137 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AC098582.1 | c.3082C>T p.R1028W | Missense Mutation (SNP) | VAF 318/1108 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs145277878; called by muse, mutect2, varscan2
- CPNE6 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 261/703 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.061); catalogued as rs377488418; called by muse, mutect2, varscan2
- JAG1 | c.1057G>C p.E353Q | Missense Mutation (SNP) | VAF 275/1099 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as CM003441, COSV99653374; called by muse, mutect2, varscan2
- KBTBD4 | c.888_889insGGG p.R296_R297insG | In Frame Ins (INS) | VAF 128/438 reads (29%) | catalogued as COSV58597484; called by mutect2, pindel, varscan2
- KRT12 | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 58/1115 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs770184655, COSV52429589; called by muse, mutect2
- PATZ1 | c.1748A>G p.N583S | Missense Mutation (SNP) | VAF 302/761 reads (40%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.98); catalogued as rs1356999048; called by muse, mutect2, varscan2
- POTEG | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 121/1346 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs145666754, COSV101611982; called by muse, mutect2
- SEC16B | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 113/1210 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.288); catalogued as rs770506272, COSV57623810; called by muse, mutect2
- ST6GALNAC4 | c.170G>A p.S57N | Missense Mutation (SNP) | VAF 52/853 reads (6%) | PolyPhen benign (0.054); catalogued as rs1383878242; called by muse, mutect2
- SYP | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 31/304 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs782248808, COSV54294864; called by muse, mutect2, varscan2
- BCKDHB | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 54/783 reads (7%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.025); called by muse, mutect2
- CBLC | c.1067A>G p.E356G | Missense Mutation (SNP) | VAF 27/453 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- CXCR3 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 82/140 reads (59%) | SIFT tolerated (0.2); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- FIP1L1 | c.1499+1G>T p.X500_splice | Splice Site (SNP) | VAF 22/699 reads (3%) | called by muse, mutect2
- GHRHR | c.974+6G>C | Splice Region (SNP) | VAF 207/590 reads (35%) | called by muse, mutect2, varscan2
- NEXN | c.724C>T p.L242F | Missense Mutation (SNP) | VAF 31/1002 reads (3%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- PCCA | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 43/856 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.948); called by muse, mutect2
- SF3A2 | c.1327C>T p.P443S | Missense Mutation (SNP) | VAF 181/324 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- SLC25A17 | c.420C>A p.D140E | Missense Mutation (SNP) | VAF 71/886 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.022); called by muse, mutect2
- UBE3B | c.631-5T>G | Splice Region (SNP) | VAF 88/837 reads (11%) | called by muse, mutect2, varscan2
- UNC80 | c.3369A>T p.K1123N | Missense Mutation (SNP) | VAF 73/1200 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); called by muse, mutect2
- CEP162 | c.1044G>A p.E348= | Silent (SNP) | VAF 74/968 reads (8%) | called by muse, mutect2
- POLM | c.1077C>T p.L359= | Silent (SNP) | VAF 47/573 reads (8%) | catalogued as COSV54241418; called by muse, mutect2
- IGFN1 | c.1241+1676T>G | Intron (SNP) | VAF 177/464 reads (38%) | called by muse, mutect2, varscan2
- PCBP2 | c.376-90C>G | Intron (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
